Somatic mutation profile of tumor specimen C3L-07154-02 (aliquot CPT0461550006) from CPTAC case C3L-07154, project CPTAC-3 (Stomach — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 53.8 years (19,644 days).
Specimen C3L-07154-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Stomach; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8784b89d-df12-45ed-9135-95b1443774c3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-07154-71 (Blood Derived Normal), aliquot CPT0460270002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d6b56bc5-8a75-49c2-a2e7-81f602c9a41d

The open-access MAF lists 84 somatic variants for this specimen: 63 protein-altering or splice-affecting, 20 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 55, Silent 20, Nonsense Mutation 3, Frame Shift Del 2, Frame Shift Ins 1, Splice Site 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOBEC3C | c.518G>C p.G173A | Missense Mutation (SNP) | VAF 24/295 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.038); catalogued as COSV99329171; called by muse, mutect2
- ARMC9 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 109/254 reads (43%) | SIFT tolerated (0.95); PolyPhen benign (0.025); catalogued as COSV63020697; called by muse, mutect2, varscan2
- BAHCC1 | c.7491G>C p.K2497N | Missense Mutation (SNP) | VAF 39/311 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1555659860; called by muse, mutect2, varscan2
- C18orf63 | c.1904G>T p.R635M | Missense Mutation (SNP) | VAF 60/318 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as COSV74057739; called by mutect2, varscan2
- DLEU7 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 93/717 reads (13%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs1039752142; called by muse, mutect2, varscan2
- DPF1 | c.455C>T p.T152M | Missense Mutation (SNP) | VAF 53/460 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.357); catalogued as rs368544567; called by muse, mutect2, varscan2
- FCN2 | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 62/360 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.011); catalogued as rs766924885, COSV52477956; called by muse, mutect2, varscan2
- FGFR1OP2 | c.191C>T p.T64M | Missense Mutation (SNP) | VAF 29/242 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.873); catalogued as rs143326108; called by muse, mutect2, varscan2
- HEXIM2 | c.668G>A p.R223Q | Missense Mutation (SNP) | VAF 51/612 reads (8%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.781); catalogued as rs1310938581; called by muse, mutect2
- ITGA10 | c.131G>A p.S44N | Missense Mutation (SNP) | VAF 56/384 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs782652963; called by muse, mutect2, varscan2
- ITGB2 | c.1974C>A p.F658L (on ENST00000302347; = p.F634L on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/313 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.105); catalogued as COSV56609621; called by muse, mutect2, varscan2
- KLHL3 | c.1312G>A p.V438I | Missense Mutation (SNP) | VAF 24/334 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs907779058, CM122583, COSV59051978, COSV59054039; called by muse, mutect2
- LILRA4 | c.1078del p.A360Qfs*8 | Frame Shift Del (DEL) | VAF 121/700 reads (17%) | catalogued as rs765067201, COSV99392953, COSV99392960; called by mutect2, pindel, varscan2
- NFE2L3 | c.835-1G>A p.X279_splice | Splice Site (SNP) | VAF 14/157 reads (9%) | catalogued as rs1445533518; called by muse, mutect2
- PADI2 | c.1558G>T p.G520W | Missense Mutation (SNP) | VAF 41/280 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV100972021, COSV64954248; called by muse, mutect2, varscan2
- PAX4 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 48/500 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763356440, COSV58389386; called by muse, mutect2
- PDCD1LG2 | c.472G>A p.V158I | Missense Mutation (SNP) | VAF 99/443 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs141466336; called by muse, mutect2, varscan2
- PER1 | c.1408G>A p.V470M | Missense Mutation (SNP) | VAF 62/384 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1276989740, COSV100424441; called by muse, mutect2, varscan2
- PNN | c.1786_1803del p.S598_S603del | In Frame Del (DEL) | VAF 70/378 reads (19%) | catalogued as rs56343145; called by mutect2, varscan2
- RIMS2 | c.3005T>G p.L1002R (on ENST00000666250 / NM_001348490.2; = p.L810R on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 53/316 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.025); catalogued as rs770788886; called by muse, mutect2, varscan2
- SCN9A | c.1325C>T p.A442V | Missense Mutation (SNP) | VAF 30/201 reads (15%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as rs773066209, COSV57602252; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEMA6B | c.72C>G p.H24Q | Missense Mutation (SNP) | VAF 83/466 reads (18%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV56702626; called by muse, mutect2, varscan2
- SHISA4 | c.82G>A p.G28S | Missense Mutation (SNP) | VAF 38/432 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs1276185121; called by muse, mutect2
- TTN | c.67805G>T p.W22602L (on ENST00000591111; = p.W15178L on NM_003319.4) | Missense Mutation (SNP) | VAF 84/339 reads (25%) | PolyPhen probably damaging (0.997); catalogued as COSV59990304; called by muse, mutect2, varscan2
- UNC80 | c.4130G>T p.C1377F | Missense Mutation (SNP) | VAF 66/345 reads (19%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.989); catalogued as rs1444046937; called by muse, varscan2
- UQCRC2 | c.34A>G p.R12G | Missense Mutation (SNP) | VAF 38/254 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs906157914; called by muse, mutect2, varscan2
- VEPH1 | c.839G>T p.G280V | Missense Mutation (SNP) | VAF 85/449 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.356); catalogued as rs1269343430; called by muse, mutect2, varscan2
- VWF | c.7393G>A p.V2465M | Missense Mutation (SNP) | VAF 85/403 reads (21%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.635); catalogued as rs375655409; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZGRF1 | c.973A>T p.S325C | Missense Mutation (SNP) | VAF 51/430 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1226190518; called by muse, mutect2, varscan2
- AKAP6 | c.1103C>T p.T368I | Missense Mutation (SNP) | VAF 101/448 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- ANK1 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 42/319 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- AOC3 | c.1357G>T p.G453W | Missense Mutation (SNP) | VAF 110/574 reads (19%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP1A3 | c.1222G>A p.D408N (on ENST00000545399 / NM_001256214.2; = p.D395N on NM_152296.5) | Missense Mutation (SNP) | VAF 41/289 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- BSN | c.3875A>T p.N1292I | Missense Mutation (SNP) | VAF 90/438 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); called by mutect2, varscan2
- CALR3 | c.201A>T p.Q67H | Missense Mutation (SNP) | VAF 31/269 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTNAP2 | c.1382T>G p.V461G | Missense Mutation (SNP) | VAF 67/360 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CPA4 | c.281T>G p.L94R | Missense Mutation (SNP) | VAF 73/281 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- DLL1 | c.1615C>T p.Q539* | Nonsense Mutation (SNP) | VAF 92/738 reads (12%) | called by muse, mutect2, varscan2
- DOLK | c.433G>A p.G145S | Missense Mutation (SNP) | VAF 73/443 reads (16%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.83); called by muse, mutect2, varscan2
- GPR75 | c.169T>C p.S57P | Missense Mutation (SNP) | VAF 88/565 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HAPLN4 | c.844C>T p.R282* | Nonsense Mutation (SNP) | VAF 99/524 reads (19%) | called by muse, mutect2, varscan2
- HPS1 | c.6G>C p.K2N | Missense Mutation (SNP) | VAF 64/322 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- IKBKB | c.1379G>A p.R460Q | Missense Mutation (SNP) | VAF 48/282 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- KDM3B | c.1564T>C p.S522P | Missense Mutation (SNP) | VAF 39/468 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- LILRB4 | c.1164G>C p.K388N (on ENST00000391733 / NM_001278428.3; = p.K387N on NM_001278426.3) | Missense Mutation (SNP) | VAF 110/730 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.301); called by muse, varscan2
- MALRD1 | c.3131C>A p.T1044K | Missense Mutation (SNP) | VAF 36/494 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.422); called by muse, mutect2
- NALCN | c.1561T>C p.S521P | Missense Mutation (SNP) | VAF 60/408 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NES | c.2135G>T p.R712I | Missense Mutation (SNP) | VAF 74/485 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- NME5 | c.200dup p.N69Qfs*18 | Frame Shift Ins (INS) | VAF 55/417 reads (13%) | called by mutect2, pindel, varscan2
- NRAP | c.5079G>C p.Q1693H (on ENST00000359988 / NM_001322945.2; = p.Q1658H on NM_006175.4) | Missense Mutation (SNP) | VAF 48/303 reads (16%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OBSL1 | c.452C>A p.A151E | Missense Mutation (SNP) | VAF 109/714 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); called by muse, mutect2, varscan2
- OR52E8 | c.787T>C p.S263P | Missense Mutation (SNP) | VAF 32/396 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- RTL1 | c.388G>A p.G130R | Missense Mutation (SNP) | VAF 92/412 reads (22%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SACS | c.5545G>T p.V1849L | Missense Mutation (SNP) | VAF 80/603 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- SH3GLB2 | c.742A>G p.N248D | Missense Mutation (SNP) | VAF 48/260 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- SHISA9 | c.148G>A p.A50T | Missense Mutation (SNP) | VAF 108/662 reads (16%) | SIFT tolerated (0.34); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SLC1A6 | c.1301C>A p.A434D | Missense Mutation (SNP) | VAF 70/428 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TERB1 | c.1276G>T p.E426* | Nonsense Mutation (SNP) | VAF 33/126 reads (26%) | called by mutect2, varscan2
- TMC1 | c.1825A>T p.M609L | Missense Mutation (SNP) | VAF 72/420 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- TNN | c.311G>C p.S104T | Missense Mutation (SNP) | VAF 84/517 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- UBE4B | c.3180G>C p.Q1060H (on ENST00000343090 / NM_001105562.3; = p.Q931H on NM_006048.5) | Missense Mutation (SNP) | VAF 39/301 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF425 | c.290A>G p.K97R | Missense Mutation (SNP) | VAF 60/306 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0.354); called by muse, mutect2, varscan2
- ZSWIM5 | c.2372_2384del p.Y791Sfs*18 | Frame Shift Del (DEL) | VAF 61/408 reads (15%) | called by mutect2, pindel, varscan2
- CIPC | c.333G>A p.S111= | Silent (SNP) | VAF 58/291 reads (20%) | catalogued as rs185492654; called by muse, mutect2, varscan2
- FADS3 | c.741C>T p.S247= | Silent (SNP) | VAF 61/258 reads (24%) | catalogued as rs766279636, COSV53880172; called by muse, mutect2, varscan2
- FAM178B | c.156C>T p.A52= | Silent (SNP) | VAF 105/369 reads (28%) | catalogued as rs759069690, COSV100013930, COSV59972727; called by muse, mutect2, varscan2
- GABPA | c.456C>T p.I152= | Silent (SNP) | VAF 27/315 reads (9%) | called by muse, mutect2, varscan2
- HIPK2 | c.3381G>A p.A1127= | Silent (SNP) | VAF 127/570 reads (22%) | catalogued as rs776716441, COSV69207969; called by muse, varscan2
- IGKV4-1 | c.309C>T p.S103= | Silent (SNP) | VAF 48/343 reads (14%) | catalogued as rs372416266; called by muse, varscan2
- KRTAP4-5 | c.393C>T p.C131= | Silent (SNP) | VAF 139/774 reads (18%) | called by muse, mutect2, varscan2
- NOTO | c.141C>T p.S47= | Silent (SNP) | VAF 121/708 reads (17%) | called by muse, mutect2, varscan2
- NUP210 | c.876C>G p.P292= | Silent (SNP) | VAF 74/480 reads (15%) | catalogued as rs756600429; called by muse, mutect2
- PLCD1 | c.531C>T p.D177= | Silent (SNP) | VAF 49/316 reads (16%) | catalogued as rs368360654; called by muse, mutect2, varscan2
- POLRMT | c.2781C>T p.G927= | Silent (SNP) | VAF 59/387 reads (15%) | catalogued as rs771318562; called by muse, mutect2, varscan2
- PTPRB | c.2931C>T p.A977= | Silent (SNP) | VAF 69/2028 reads (3%) | catalogued as rs1185624385; called by muse, mutect2
- RET | c.906C>T p.D302= | Silent (SNP) | VAF 72/435 reads (17%) | catalogued as rs768934031; ClinVar: likely benign; called by muse, mutect2, varscan2
- SPATA17 | c.888T>G p.S296= | Silent (SNP) | VAF 33/269 reads (12%) | catalogued as COSV65125776; called by muse, mutect2, varscan2
- TMEM179B | c.552C>G p.V184= | Silent (SNP) | VAF 85/431 reads (20%) | catalogued as rs149169067; called by muse, mutect2, varscan2
- TMPRSS4 | c.96G>A p.V32= | Silent (SNP) | VAF 45/435 reads (10%) | called by muse, mutect2
- VAX1 | c.843C>T p.L281= | Silent (SNP) | VAF 48/645 reads (7%) | catalogued as rs1320510358; called by muse, mutect2
- ZMYM2 | c.3624A>C p.G1208= | Silent (SNP) | VAF 61/463 reads (13%) | called by muse, mutect2, varscan2
- ZNF679 | c.222T>G p.P74= | Silent (SNP) | VAF 30/353 reads (8%) | called by muse, mutect2
- ZNF91 | c.534A>G p.G178= | Silent (SNP) | VAF 42/292 reads (14%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+16476_1514+16494del | Intron (DEL) | VAF 37/361 reads (10%) | called by mutect2, pindel
